Gene-level copy-number profile of tumor specimen HCM-BROD-0051-C64-06B from HCMI case HCM-BROD-0051-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 2.6 years (941 days).
Specimen HCM-BROD-0051-C64-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66802f21-2f18-4a78-aef1-b19888458ec8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0051-C64-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,141 have no estimate.
https://portal.gdc.cancer.gov/files/f0af7557-7593-442a-9dfc-6eae083d1378

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 161; copy number 2: 498; copy number 3: 4,015; copy number 4: 30,991; copy number 5: 17,871; copy number 6: 2,038; copy number 7: 1,251; copy number 8: 908; copy number 9: 308; copy number 10: 175; copy number 11: 61; copy number 12: 31; copy number 13: 27; copy number 14: 56; copy number 15: 9; copy number 16: 12; copy number 17: 13; copy number 18: 12; copy number 19: 2; copy number 20: 5; copy number 22: 4; copy number 23: 1; copy number 25: 4; copy number 26: 2; copy number 27: 3; copy number 31: 11; copy number 33: 1; copy number 40: 1; copy number 48: 7; copy number 51: 1; copy number 56: 2; copy number 75: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 749 genes in 327 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:26,980,165–27,012,850, 5 genes, copy number 10–11: RPL12P13, AL356390.1, OSTCP2, TRNP1, TENT5B.
- chr1:28,643,228–28,871,267, 7 genes, copy number 9 (within-gene range 5–9): LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1, YTHDF2, OPRD1.
- chr1:32,072,031–32,176,568, 5 genes, copy number 9 (within-gene range 5–9): TMEM39B, MIR5585, Metazoa_SRP, KPNA6, AL049795.2.
- chr1:32,457,835–32,686,211, 7 genes, copy number 9 (within-gene range 8–9): RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4.
- chr1:52,020,131–52,055,191, 5 genes, copy number 10 (within-gene range 8–10): TXNDC12, AL445685.3, KTI12, AL445685.1, TXNDC12-AS1.
- chr1:120,963,645–121,117,257, 8 genes, copy number 18: AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1.
- chr1:121,573,946–143,500,512, 6 genes, copy number 9–31: LINC01691, AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr1:145,911,350–145,977,811, 8 genes, copy number 10 (within-gene range 7–10): PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2.
- chr1:153,981,617–154,155,116, 7 genes, copy number 9: RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698.
- chr1:224,175,476–224,228,043, 5 genes, copy number 9 (within-gene range 7–9): AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4.
- chr5:134,601,149–134,863,433, 10 genes, copy number 9–10: SAR1B, RNU6-1311P, SEC24A, RNU6-1164P, RNU6-757P, CAMLG, DDX46, AC010301.1, C5orf24, AC006077.1.
- chr6:149,561,152–149,648,972, 8 genes, copy number 9–10: AL078581.3, GINM1, AL078581.4, AL078581.2, RPS18P9, AL078581.1, KATNA1, Y_RNA.
- chr7:63,291,518–63,359,306, 8 genes, copy number 9–48: ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr7:65,247,608–65,357,176, 5 genes, copy number 9–14: AC104073.1, AC104073.4, AC104073.3, RSL24D1P3, AC092685.1.
- chr8:42,697,366–42,844,876, 6 genes, copy number 9–10: CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1.
- chr9:64,878,790–65,285,209, 6 genes, copy number 11–14: AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, FOXD4L5.
- chr9:125,194,649–125,367,207, 7 genes, copy number 9–11: RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P.
- chr10:68,341,107–68,694,487, 10 genes, copy number 9–11 (within-gene range 2–11): RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP, TET1, COX20P1.
- chr10:68,698,500–68,792,377, 6 genes, copy number 9: AL513534.2, AL513534.3, CCAR1, Y_RNA, SNORD98, AL513534.1.
- chr10:73,346,936–73,433,561, 5 genes, copy number 9 (within-gene range 9–10): Y_RNA, ANXA7, AL512656.1, RPL26P6, MSS51.
- chr11:47,465,933–47,594,411, 10 genes, copy number 10–12 (within-gene range 4–12): CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4.
- chr12:50,219,604–50,396,622, 6 genes, copy number 9–12 (within-gene range 8–13): AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1.
- chr12:112,026,689–112,108,796, 4 genes, copy number 10 (within-gene range 10–15): NAA25, MIR3657, AC073575.1, Y_RNA.
- chr12:120,438,090–120,463,749, 5 genes, copy number 9 (within-gene range 6–9): COX6A1, AL021546.1, TRIAP1, GATC, RPL31P52.
- chr12:123,363,868–123,436,717, 4 genes, copy number 9–11 (within-gene range 8–11): SBNO1-AS1, MIR8072, KMT5A, RILPL2.
- chr14:18,899,942–19,003,752, 7 genes, copy number 25–27: NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P.
- chr14:34,515,938–34,630,160, 8 genes, copy number 11–12: EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3.
- chr14:58,370,023–58,427,531, 4 genes, copy number 9 (within-gene range 4–9): AL139021.2, TOMM20L, AL139021.1, TIMM9.
- chr15:20,826,454–20,961,581, 10 genes, copy number 10–31: AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2, NF1P1, MIR5701-1, OR11J2P.
- chr15:21,053,004–21,130,095, 4 genes, copy number 19–40: AC037471.1, BCAR1P2, RN7SL400P, AC126335.1.
- chr15:21,293,653–21,951,323, 38 genes, copy number 14–26: AC068446.1, AC068446.2, RNU6-1235P, AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, NF1P2, MIR5701-3.
- chr15:21,990,074–22,095,857, 8 genes, copy number 17 (within-gene range 5–55): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4.
- chr15:41,320,794–41,483,563, 5 genes, copy number 10 (within-gene range 8–10): NUSAP1, AC087721.1, NDUFAF1, RTF1, RNU6-1169P.
- chr16:68,737,292–69,085,182, 12 genes, copy number 9: CDH1, RNA5SP429, AC099314.1, FTLP14, TANGO6, Y_RNA, U7, AC009137.1, AC009137.2, RNU6-898P, AC009027.1, RPS2P45.
- chr17:2,303,383–2,336,657, 5 genes, copy number 13 (within-gene range 5–13): SRR, HNRNPA1P16, TSR1, SNORD91B, SNORD91A.
- chr17:30,792,372–30,895,869, 7 genes, copy number 10–11: AC127024.5, AC127024.6, AC127024.1, ATAD5, AC130324.2, RNU6-298P, AC130324.1.
- chr17:30,964,935–30,999,911, 6 genes, copy number 9: AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7.
- chr17:61,942,605–62,065,278, 4 genes, copy number 9 (within-gene range 7–9): MED13, AC018628.1, RN7SL800P, AC018628.2.
- chr19:10,486,125–10,692,417, 13 genes, copy number 9–10: KEAP1, AC011461.1, S1PR5, ATG4D, RNU7-140P, MIR1238, KRI1, CDKN2D, AP1M2, AC011475.1, SLC44A2, ILF3-DT, ILF3.
- chr20:34,347,671–34,476,787, 8 genes, copy number 9–10 (within-gene range 9–12): AL356299.1, Y_RNA, CDC42P1, ITCH-AS1, ITCH-IT1, MIR644A, FDX1P1, AL109923.1.

Autosomal genes at a single copy (total copy number 1): 161. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
